Somatic mutation profile of tumor specimen TCGA-HT-8111-01A (aliquot TCGA-HT-8111-01A-11D-2395-08) from TCGA case TCGA-HT-8111, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 32.3 years (11,810 days).
Specimen TCGA-HT-8111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee74cb2a-f835-493d-b178-e6e4d9e67ee3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8111-10A (Blood Derived Normal), aliquot TCGA-HT-8111-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b35fa503-b72f-4ef3-9214-fbea996981b2

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 58/97 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56645243; called by muse, mutect2
- CALHM2 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV53296911; called by muse, mutect2, varscan2
- IL22RA1 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV54629397, COSV54629426; called by muse, mutect2, varscan2
- KIAA1109 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52682743; called by muse, mutect2, varscan2
- KLHL28 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.096); catalogued as COSV61888786; called by muse, mutect2
- KMT2D | c.13418A>C p.Q4473P | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV56463129; called by muse, mutect2, varscan2
- WNK2 | c.4499C>A p.A1500D (on ENST00000297954 / NM_001282394.1; = p.A1463D on NM_006648.3) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV52950270; called by muse, mutect2
- SPAG17 | c.4409_4419del p.I1470Rfs*33 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- ETFDH | c.402G>A p.K134= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57015605; called by muse, mutect2, varscan2
